Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4347, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4347-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

with right renal mass

Specimens Submitted:

- 1: Kidney, right, satellite tumor, excision
- 2: Kidney, right, partial nephrectomy
- 3: Kidney, right, deep margin #1, excision
- 4: Kidney, right, deep margin #2; excision

DIAGNOSIS:

1. Kidney, right, "satellite tumor", excision:
Benign intra-renal (ectopic) adrenal tissue

2. Kidney, right, partial nephrectomy:

Tumor Type:
Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:
Nuclear grade II/IV

Tumor Size:
Greatest diameter is 3.0 cm.

Local Invasion (for renal cortical types):
Not identified

Renal Vein Invasion:
Not identified
Tumor invades muscular branches of the renal vein in the renal hilum

Surgical Margins:
Tumor present at renal parenchymal margin (for partial nephrectomy specimens only)
(Not in the frozen section and the frozen section control. For final margins see parts 3 and 4.)

Non-Neoplastic Kidney:
Mild arteriosclerotic changes; a small medullary fibroma

Adrenal Gland:
Not identified

Lymph Nodes:
Not identified

Staging for renal cell carcinoma/oncocytoma:
pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

3. Kidney, right, deep margin #1, excision:
Benign kidney parenchyma
4. Kidney, right, deep margin #2; excision:
Benign fibroadipose and urothelial tissue

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	

Gross Description:

1. The specimen is received fresh, labeled "satellite tumor right kidney" and consists of a single piece of brown soft tissue measuring 0.5 x 0.4 x 0.1 cm. The is entirely submitted.

Summary of sections:
U - undesignated

2). The specimen is received fresh, labeled "right renal tumor, stitch marks deep margin". It consists of a 5.0 x 3.5 x 2.5 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal one well circumscribed bright-yellow mass, measuring 3.0 x 2.5 x 2.0 cm. The clearance from the resection margin is less than 0.1 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted.

Summary of sections:
FSC - frozen section control
T - tumor
RS - representative sections

3. The specimen is received fresh, labeled "deep margin # 1, right renal tumor" and consists of a piece of brown soft tissue measuring 1.2 x 0.4 x 0.2 cm. The entire specimen submitted.

Summary of sections:
U - undesignated

4. The specimen is received fresh, labeled "deep margin # 2, right renal tumor" and consists of a piece of brown soft tissue measuring 1. x 0.3 x 0.2 cm. The entire specimen submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: Kidney, right, satellite tumor, excision

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Block	Sect. Site	PCs
1	u	1

Part 2: Kidney, right, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
2	rs	2
6	t	7

Part 3: Kidney, right, deep margin #1, excision

Block	Sect. Site	PCs
1	u	1

Part 4: Kidney, right, deep margin #2; excision

Block	Sect. Site	PCs
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 2) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. MARGIN FREE ON FROZEN SECTION (A THIN CAPSULE PRESENT AT MARGIN.
PERMANENT DIAGNOSIS: SEE FINAL

Source: NCI Genomic Data Commons file 1d3d0f12-db6d-4329-98dd-d4d8bdf277bd (TCGA-BP-4347.8DDCCDD9-EC03-4456-BCD2-2071B861DCA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).